Somatic mutation profile of tumor specimen TCGA-61-1737-01A (aliquot TCGA-61-1737-01A-01W-0639-09) from TCGA case TCGA-61-1737, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 42.5 years (15,515 days).
Specimen TCGA-61-1737-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04ce7d3e-87a5-4050-8737-5ff7e20d829e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-1737-11A (Solid Tissue Normal), aliquot TCGA-61-1737-11A-01W-0639-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f113ecfe-9401-42b1-850a-b947f43bce79

The open-access MAF lists 100 somatic variants for this specimen: 78 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 20, Frame Shift Del 4, In Frame Del 4, Splice Site 2, 3'UTR 1, Intron 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.993+1G>A p.X331_splice | Splice Site (SNP) | VAF 45/121 reads (37%) | hotspot (GDC flag); catalogued as rs11575997, CD002536, COSV52663229, COSV52699909, COSV52752826; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.841G>T p.D281Y | Missense Mutation (SNP) | VAF 36/96 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764146326, CD137626, CM076566, CM153816, COSV52671054, COSV52674651, COSV52678614; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AAR2 | c.1111G>T p.A371S | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as rs759400956, COSV57925058; called by muse, mutect2, varscan2
- ADAMTS4 | c.1155C>G p.S385R | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.062); catalogued as COSV63488337; called by muse, mutect2, varscan2
- ADAMTSL4 | c.460C>G p.P154A | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55004161; called by muse, mutect2, varscan2
- AKR1C4 | c.549G>T p.K183N | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99578490; called by muse, mutect2
- BRCA2 | c.3674C>A p.T1225K | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV101203881; called by muse, mutect2
- BRINP3 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV66534364; called by muse, varscan2
- CAP1 | c.848A>G p.N283S | Missense Mutation (SNP) | VAF 40/904 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1365983059, COSV100471817; called by muse, mutect2
- CD163 | c.1394A>G p.Y465C | Missense Mutation (SNP) | VAF 30/466 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.738); catalogued as COSV100775617; called by muse, mutect2
- CHD7 | c.2426G>A p.R809H | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1313215076, COSV71113191; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYP11B1 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.284); catalogued as rs746083604, COSV52825877; called by muse, mutect2, varscan2
- CYP4A22 | c.142C>T p.L48F | Missense Mutation (SNP) | VAF 64/221 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1485938745, COSV53741605; called by muse, varscan2
- FLT4 | c.4031G>A p.S1344N | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.033); catalogued as COSV56117192; called by muse, mutect2, varscan2
- FOSB | c.973C>A p.Q325K | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.037); catalogued as COSV62279061; called by muse, mutect2, varscan2
- GARNL3 | c.3001C>G p.L1001V | Missense Mutation (SNP) | VAF 82/190 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.138); catalogued as COSV59228974; called by muse, varscan2
- GRIN2B | c.1424C>A p.T475N | Missense Mutation (SNP) | VAF 120/590 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV74207034; called by muse, mutect2, varscan2
- HOXD10 | c.658G>C p.E220Q | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.34); PolyPhen benign (0.177); catalogued as COSV50893286, COSV50893495; called by muse, mutect2, varscan2
- IGF2R | c.1138G>T p.A380S | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0.254); catalogued as COSV63631380; called by muse, mutect2, varscan2
- IQGAP2 | c.4603C>G p.L1535V | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.408); catalogued as COSV57178244; called by muse, mutect2, varscan2
- IQSEC1 | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as rs200196417; called by muse, mutect2, varscan2
- IQSEC2 | c.3023A>G p.K1008R (on ENST00000642864 / NM_001111125.3; = p.K803R on NM_015075.2) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV64727244; called by muse, varscan2
- IQUB | c.1361T>C p.I454T | Missense Mutation (SNP) | VAF 10/265 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.07); catalogued as rs1223326667, COSV100226712; called by muse, mutect2
- KIAA1109 | c.9162G>C p.M3054I | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as COSV52685542; called by muse, mutect2, varscan2
- KIDINS220 | c.3236A>G p.Y1079C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs760475551, COSV56757155; called by mutect2, varscan2
- KIFC1 | c.880G>C p.E294Q | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV65737785; called by muse, mutect2, varscan2
- KLK1 | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56827815; called by muse, mutect2, varscan2
- KMT2A | c.3127C>G p.L1043V | Missense Mutation (SNP) | VAF 85/220 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.883); catalogued as COSV63290193; called by muse, mutect2, varscan2
- MTHFD2 | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99902888; called by muse, mutect2, varscan2
- MUC15 | c.977A>G p.D326G | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as COSV55556217; called by muse, mutect2, varscan2
- MYH9 | c.1258G>T p.A420S | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as COSV53385252, COSV53390931; called by muse, varscan2
- OR5M1 | c.448A>G p.M150V | Missense Mutation (SNP) | VAF 14/273 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1452474856, COSV101591526; called by muse, mutect2
- PCDHGA12 | c.1635C>A p.N545K | Missense Mutation (SNP) | VAF 57/248 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.5); catalogued as rs149830124, COSV52761203; called by muse, mutect2, varscan2
- PIBF1 | c.2103G>T p.E701D | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.022); catalogued as COSV100411190; called by muse, mutect2
- PIGX | c.322G>A p.V108M | Missense Mutation (SNP) | VAF 130/215 reads (60%) | SIFT tolerated (0.14); PolyPhen benign (0.146); catalogued as COSV56360619; called by muse, mutect2, varscan2
- PIK3CD | c.1392C>A p.N464K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.947); catalogued as COSV63130633; called by muse, mutect2, varscan2
- POLQ | c.6974C>A p.S2325* | Nonsense Mutation (SNP) | VAF 18/282 reads (6%) | catalogued as COSV99951538; called by muse, mutect2
- PRRC2C | c.1882C>A p.P628T (on ENST00000367742; = p.P626T on NM_015172.4) | Missense Mutation (SNP) | VAF 8/217 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as COSV100144615; called by muse, mutect2
- PTPN7 | c.826G>A p.E276K (on ENST00000495688; = p.E315K on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs1257700327, COSV58311655; called by muse, mutect2
- PTPRZ1 | c.1159C>A p.Q387K | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66442382; called by muse, mutect2, varscan2
- RAD54L | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 100/342 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1269019049, COSV64336708; called by muse, varscan2
- RAPGEF6 | c.4578C>G p.H1526Q | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.381); catalogued as COSV57247572, COSV57252079; called by muse, mutect2, varscan2
- RNF19A | c.256G>T p.G86C | Missense Mutation (SNP) | VAF 56/337 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.343); catalogued as COSV61992402; called by muse, varscan2
- RPL12 | c.478G>C p.V160L | Missense Mutation (SNP) | VAF 10/276 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100031110; called by muse, mutect2
- SAMD9L | c.3127C>A p.Q1043K | Missense Mutation (SNP) | VAF 24/534 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV100560277; called by muse, mutect2
- SCN4A | c.1434C>A p.H478Q | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV101438307; called by muse, mutect2
- SENP6 | c.1784G>T p.C595F | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100518973, COSV59193691; called by muse, mutect2
- SLC22A9 | c.376T>A p.S126T | Missense Mutation (SNP) | VAF 60/221 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.088); catalogued as COSV54169016; called by muse, mutect2, varscan2
- SLC44A5 | c.1768G>C p.D590H | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs754303886, COSV100901021; called by muse, mutect2
- SNCAIP | c.736G>T p.G246C | Missense Mutation (SNP) | VAF 111/172 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); catalogued as COSV54417089; called by muse, mutect2, varscan2
- SPTBN4 | c.750G>T p.Q250H | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.836); catalogued as COSV58956003; called by muse, mutect2, varscan2
- SYNE1 | c.12374C>A p.A4125D (on ENST00000367255 / NM_182961.4; = p.A4054D on NM_033071.3) | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV55054270; called by muse, mutect2, varscan2
- SYNE2 | c.13692G>T p.Q4564H | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV100646608; called by muse, mutect2
- SYNE2 | c.20206G>A p.G6736R | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.823); catalogued as rs1227345502, COSV59961871; called by muse, mutect2, varscan2
- TCN1 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 52/241 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57254099, COSV57254456; called by muse, mutect2, varscan2
- TLE3 | c.1283dup p.M429Dfs*27 | Frame Shift Ins (INS) | VAF 4/42 reads (10%) | catalogued as rs770951788; called by pindel, varscan2
- TLK2 | c.709G>T p.D237Y | Missense Mutation (SNP) | VAF 10/274 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100408645; called by muse, mutect2
- TNIK | c.2417C>A p.A806E | Missense Mutation (SNP) | VAF 19/494 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV99454864; called by muse, mutect2
- TTC21A | c.1804C>G p.P602A | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as COSV57188005; called by muse, varscan2
- TTN | c.94129C>A p.Q31377K (on ENST00000591111; = p.Q23953K on NM_003319.4) | Missense Mutation (SNP) | VAF 10/278 reads (4%) | PolyPhen benign (0.121); catalogued as COSV100593068; called by muse, mutect2
- TTN | c.93001G>T p.V31001L (on ENST00000591111; = p.V23577L on NM_003319.4) | Missense Mutation (SNP) | VAF 46/381 reads (12%) | PolyPhen probably damaging (0.99); catalogued as COSV60230724; called by muse, mutect2, varscan2
- UBE3C | c.551T>G p.V184G | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV61954934; called by muse, varscan2
- UBR2 | c.2091G>T p.M697I | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as COSV100867351; called by muse, mutect2
- UPF1 | c.2630C>G p.A877G (on ENST00000599848 / NM_001297549.2; = p.A866G on NM_002911.4) | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV99438739; called by muse, mutect2
- ZIC5 | c.1891G>A p.A631T | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs766276619, COSV57436872; called by muse, mutect2, varscan2
- ZNF10 | c.339G>T p.M113I | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99939829; called by muse, mutect2
- ZNF772 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.676); catalogued as COSV58411319; called by muse, mutect2, varscan2
- ACAD11 | c.656_672del p.I219Tfs*3 | Frame Shift Del (DEL) | VAF 38/194 reads (20%) | called by mutect2, varscan2
- ACOT1 | c.879_884del p.D294_V295del | In Frame Del (DEL) | VAF 29/119 reads (24%) | called by mutect2, varscan2
- ACOT2 | c.1065_1070del p.D356_V357del | In Frame Del (DEL) | VAF 12/24 reads (50%) | called by mutect2, varscan2
- ADAMTS6 | c.3061_3064del p.R1021Gfs*19 | Frame Shift Del (DEL) | VAF 15/81 reads (19%) | called by mutect2, pindel, varscan2
- CNR1 | c.62_85del p.L21_I28del | In Frame Del (DEL) | VAF 21/111 reads (19%) | called by mutect2, pindel, varscan2
- HS3ST4 | c.1266_1302del p.D423Sfs*3 | Frame Shift Del (DEL) | VAF 10/64 reads (16%) | called by mutect2, pindel
- KCNH3 | c.1115A>G p.H372R | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NMRK1 | c.32_43del p.V11_S14del | In Frame Del (DEL) | VAF 44/163 reads (27%) | called by mutect2, pindel, varscan2
- TAF15 | c.737C>A p.S246Y (on ENST00000605844 / NM_139215.3; = p.S243Y on NM_003487.4) | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- TTN | c.39090_39091+31del p.X13030_splice (on ENST00000591111; = p.X5606_splice on NM_003319.4) | Splice Site (DEL) | VAF 12/50 reads (24%) | called by mutect2, pindel
- WDR64 | c.1414_1424del p.T472* | Frame Shift Del (DEL) | VAF 26/86 reads (30%) | called by pindel, varscan2
- APOH | c.144G>A p.T48= | Silent (SNP) | VAF 28/379 reads (7%) | catalogued as rs775234915, COSV52771958, COSV99235642; called by muse, mutect2
- BBS4 | c.717C>A p.I239= | Silent (SNP) | VAF 5/61 reads (8%) | catalogued as COSV99166383; called by muse, mutect2
- CLCNKB | c.504T>A p.P168= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV100990184; called by muse, mutect2
- COL14A1 | c.2511G>A p.V837= | Silent (SNP) | VAF 29/237 reads (12%) | catalogued as COSV52863008; called by muse, mutect2, varscan2
- HKDC1 | c.2622G>A p.L874= | Silent (SNP) | VAF 52/402 reads (13%) | catalogued as COSV100664620, COSV63578485; called by muse, mutect2, varscan2
- HOOK2 | c.1776C>T p.D592= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV53403271; called by muse, mutect2, varscan2
- IRF5 | c.360C>A p.V120= | Silent (SNP) | VAF 3/33 reads (9%) | catalogued as COSV99977474; called by muse, mutect2
- MINDY4 | c.1896C>A p.I632= | Silent (SNP) | VAF 18/250 reads (7%) | catalogued as COSV99518114; called by muse, mutect2
- MTHFD2 | c.126A>C p.G42= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as COSV99902890; called by muse, mutect2, varscan2
- MYO1B | c.3192C>A p.L1064= (on ENST00000304164; = p.L1006= on NM_012223.5) | Silent (SNP) | VAF 15/191 reads (8%) | catalogued as COSV100268581, COSV100268586; called by muse, mutect2
- NCOR2 | c.1743C>A p.R581= | Silent (SNP) | VAF 14/234 reads (6%) | catalogued as COSV100656775; called by muse, mutect2
- PCARE | c.225T>C p.C75= | Silent (SNP) | VAF 52/151 reads (34%) | catalogued as COSV59056605; called by muse, varscan2
- PSG5 | c.930G>A p.K310= | Silent (SNP) | VAF 90/439 reads (21%) | catalogued as COSV61654845; called by muse, mutect2, varscan2
- SORL1 | c.4251C>A p.S1417= | Silent (SNP) | VAF 14/379 reads (4%) | catalogued as COSV99492754; called by muse, mutect2
- SYNE1 | c.2598G>A p.K866= (on ENST00000367255 / NM_182961.4; = p.K873= on NM_033071.3) | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as COSV55054295; called by muse, mutect2, varscan2
- TMEM182 | c.435C>A p.L145= | Silent (SNP) | VAF 8/125 reads (6%) | catalogued as COSV101305313; called by muse, mutect2
- TRIO | c.4926A>G p.S1642= | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as COSV60090288; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1992A>G p.E664= | Silent (SNP) | VAF 12/266 reads (5%) | catalogued as COSV99837410; called by muse, mutect2
- ZNF18 | c.516A>C p.S172= | Silent (SNP) | VAF 138/440 reads (31%) | catalogued as COSV59552058; called by muse, mutect2, varscan2
- ZNF3 | c.555C>T p.S185= | Silent (SNP) | VAF 260/441 reads (59%) | catalogued as COSV52796305; called by muse, mutect2, varscan2
- ABI2 | c.*10828G>T | 3'UTR (SNP) | VAF 14/96 reads (15%) | catalogued as COSV55587195; called by muse, mutect2, varscan2
- TRAK1 | c.1963+153A>G | Intron (SNP) | VAF 28/173 reads (16%) | catalogued as COSV100409724; called by muse, mutect2, varscan2
